Somatic mutation profile of tumor specimen 0DSI9P from CCDI case PBCHBW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.1 years (6,251 days).
Specimen 0DSI9P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2311ea25-cb41-4275-9819-17d27e71305b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSI81 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44b03789-4283-4c78-b66d-02dd18986cdf

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5902C>T p.R1968* (on ENST00000358273 / NM_001042492.3; = p.R1947* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 368/1295 reads (28%) | catalogued as rs137854552, CM900173, COSV62199973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAJC11 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 71/1321 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs767142761; called by muse, mutect2
- KCTD18 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 37/1518 reads (2%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); catalogued as COSV100728983; called by muse, mutect2
- MYH10 | c.5354A>G p.N1785S | Missense Mutation (SNP) | VAF 183/1117 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs765325286; called by muse, mutect2, varscan2
- AFF4 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 192/1179 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ODF2 | c.1248C>G p.S416R (on ENST00000434106 / NM_153433.2; = p.S392R on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/734 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by muse, mutect2
- PEAK1 | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 67/858 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- IGF2BP2 | c.1368C>T p.F456= | Silent (SNP) | VAF 91/668 reads (14%) | catalogued as rs199697480; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 42/1603 reads (3%) | called by muse, mutect2
- USP11 | c.930C>G p.G310= (on ENST00000218348; = p.G267= on NM_001371072.1) | Silent (SNP) | VAF 148/857 reads (17%) | called by muse, mutect2, varscan2
- ATP1B2 | c.-143A>C | 5'UTR (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- MFF | c.39-21C>G | Intron (SNP) | VAF 76/520 reads (15%) | called by muse, mutect2, varscan2
